Somatic mutation profile of tumor specimen MBCProject_3808_T3_WES (aliquot MBCProject_3808_T3_WES_1) from CMI case MBCProject_3808, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 67.5 years (24,661 days).
Specimen MBCProject_3808_T3_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Chest Wall; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45192389-b060-49a4-9658-4c4c6dc12c61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3808_SALIVA (Saliva), aliquot MBCProject_3808_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/300136e0-33ad-4cb6-af47-427210f0951b

The open-access MAF lists 53 somatic variants for this specimen: 42 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 7, Nonsense Mutation 4, RNA 2, Splice Region 1, Intron 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 14/136 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104894104, CM014526, CX073790, COSV58704067, COSV58704478, COSV58719419; ClinVar: likely pathogenic; called by muse, mutect2
- COL1A2 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72656396, CM070824, COSV51962571; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 13/159 reads (8%) | catalogued as rs1060500122, CM110149, COSV64288740, COSV64297241; ClinVar: pathogenic; called by muse, mutect2
- BDKRB1 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV53706009, COSV53707383; called by muse, mutect2
- CASS4 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1364514405; called by muse, mutect2
- CCR7 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs746049008, COSV55850387; called by muse, mutect2, varscan2
- CHRNA2 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1370103246; called by muse, mutect2, varscan2
- CLCN2 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs886403826, COSV55603976; called by muse, mutect2
- CSPG4 | c.5938C>T p.R1980C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs750781181, COSV57900429; called by mutect2, varscan2
- F11 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV53004862; called by muse, mutect2
- FGF23 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV52976418; called by muse, mutect2
- GHSR | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53841917; called by muse, mutect2, varscan2
- GOLGA3 | c.3820G>T p.E1274* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as rs1025627053, COSV52639232; called by muse, mutect2
- IFNA5 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs774150373; called by muse, mutect2, varscan2
- KDM3B | c.4889G>A p.R1630Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as rs1233840880, COSV100069838; called by muse, mutect2, varscan2
- PKN2 | c.2866A>G p.I956V | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.04); catalogued as COSV65142851; called by muse, mutect2, varscan2
- RBMXL2 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs775110175, COSV60982312; called by muse, mutect2, varscan2
- RELN | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.955); catalogued as rs910972681, COSV58986974; called by muse, mutect2
- SHOX | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs1425206026, CM011484; called by muse, mutect2, varscan2
- STAT1 | c.1048A>T p.K350* | Nonsense Mutation (SNP) | VAF 12/145 reads (8%) | catalogued as COSV61189656; called by muse, mutect2
- TENM2 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs773543508, COSV72859296; called by muse, mutect2
- CEP120 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- CHD7 | c.135dup p.G46Rfs*15 | Frame Shift Ins (INS) | VAF 16/165 reads (10%) | called by mutect2, varscan2
- EYS | c.7144A>C p.N2382H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- FAM227B | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.41); called by muse, mutect2
- FAP | c.1815-4T>C | Splice Region (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- FBN2 | c.7709T>C p.I2570T | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2
- FN1 | c.1312G>C p.G438R | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABRE | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRS2 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.017); called by muse, mutect2
- MYOZ1 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2
- OR52N2 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.729); called by muse, mutect2
- PGM1 | c.1280G>T p.R427M | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRPF6 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RIPOR1 | c.1073T>C p.L358P (on ENST00000379312 / NM_001193522.2; = p.L354P on NM_024519.4) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- ROBO1 | c.2047C>G p.P683A | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- RPGR | c.2267G>T p.R756L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RXFP1 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2
- SI | c.4491G>A p.W1497* | Nonsense Mutation (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- SPEG | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTBN1 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZKSCAN4 | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA3 | c.3771G>A p.L1257= | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- ADAMTSL3 | c.1293C>G p.S431= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV99716724; called by mutect2, varscan2
- EBF2 | c.762C>T p.C254= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- GLUD1 | c.534G>A p.P178= | Silent (SNP) | VAF 30/240 reads (13%) | catalogued as rs764675203; called by muse, varscan2
- HNRNPA1 | c.108A>G p.Q36= | Silent (SNP) | VAF 18/219 reads (8%) | catalogued as rs28758594; called by muse, mutect2
- KATNB1 | c.708C>T p.S236= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs781979251; called by muse, varscan2
- LAMA1 | c.2916C>G p.V972= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- C22orf34 | n.117A>T | RNA (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- EIF2B5 | c.320+35C>G | Intron (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- MGP | c.-33C>G | 5'UTR (SNP) | VAF 12/179 reads (7%) | called by muse, mutect2
- SIGLEC17P | n.1156T>C | RNA (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
